Gene-level copy-number profile of tumor specimen TCGA-DK-A3IQ-01A from TCGA case TCGA-DK-A3IQ, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 74.5 years (27,194 days).
Specimen TCGA-DK-A3IQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.6ba45110-a4f7-4783-be15-5de4722c6472.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DK-A3IQ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5676a1f8-5d28-40e4-a592-c2df8ee04439

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 148; copy number 1: 16,802; copy number 2: 36,067; copy number 3: 5,487; copy number 4: 1,310; copy number 8: 1; copy number 9: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DK-A3IQ-01A-31D-A20B-01): tumor purity 0.35, ploidy 1.84, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 148 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:168,820,423–170,306,565, 38 genes: AL513210.2, AL513210.1, AL109924.4, AL109924.3, AL109924.1, AL109924.2, AL136129.1, LINC01615, LINC02544, BX322234.1, THBS2, BX322234.2, VTA1P1, LINC02519, AL009176.1, AL031315.1, AL135910.1, WDR27, C6orf120, PHF10, AL354892.2, AL354892.1, TCTE3, ERMARD, AL354892.3, LINC00242, LINC00574, AL049612.1, AL603783.1, AL596442.4, AL596442.3, AL596442.1, AL596442.2, RPL12P23, AL109910.1, AL109910.2, LINC01624, DLL1.
- chr6:170,297,876–170,330,844, 2 genes: AL078605.1, MIR4644.
- chr8:2,493,876–4,994,972, 15 genes (within-gene range 0–1): AC245519.1, AC245519.2, AC245187.2, AC245187.1, AC245123.1, AC246817.2, AC246817.1, AC115485.1, AC023296.1, CSMD1, AC026991.1, AC026991.2, RNA5SP251, AC027251.1, AC010941.1.
- chr9:20,658,309–20,995,955, 1 gene (within-gene range 0–2): FOCAD.
- chr9:20,786,927–21,278,619, 20 genes: SNORA30B, HACD4, IFNNP1, IFNB1, IFNWP4, AL390882.1, IFNW1, Y_RNA, IFNA21, IFNWP15, IFNA4, IFNWP9, IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P.
- chr9:21,967,752–24,088,051, 24 genes (within-gene range 0–2): CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1, AL365204.2, AL365204.3, AL513317.1.
- chr9:73,750,972–73,873,297, 2 genes: RNA5SP286, AL513124.1.
- chr9:122,370,530–123,268,586, 36 genes (within-gene range 0–1): PTGS1, AL359636.1, AL359636.2, OR1J1, OR1J2, OR1J4, OR1N1, OR1N2, OR1L8, OR1H1P, OR1Q1, OR1B1, OR1L1, OR1L3, TLK1P1, OR1L4, OR1L6, SKA2P1, OR5C1, PDCL, OR1K1, KRT18P67, RC3H2, SNORD90, ZBTB6, ZBTB26, AC007066.2, AC007066.3, RABGAP1, RNY1P15, AC007066.1, GPR21, AL365338.1, MIR600HG, STRBP, MIR600.
- chr14:37,171,888–38,041,442, 10 genes (within-gene range 0–1): SLC25A21-AS1, RNU6-273P, MIPOL1, RNU6-886P, AL121790.2, AL121790.1, FOXA1, TTC6, AL136296.1, RNU6-1277P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:195,003,711–195,026,370, 1 gene, copy number 8 (within-gene range 2–8): AC010983.1.
- chr4:57,841,721–57,855,271, 1 gene, copy number 9: AC104790.1.
- chr8:43,672,823–43,674,591, 2 genes, copy number 9: AC139365.2, AC139365.1.

Autosomal genes at a single copy (total copy number 1): 14,381. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
